TCGA case TCGA-12-0618 — Glioblastoma Multiforme (TCGA-GBM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Gliomas; Primary site: Brain; Tissue source site: Duke. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/f7ba48c8-46cf-40a9-8826-7e1f67d57171

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 49 years; Vital status: Dead; Days to death: 395 days (1.1 years).

Diagnoses (1)
1. Glioblastoma: ICD-O-3 morphology code: 9440/3; ICD-10 code: C71.9; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Brain, NOS; Classification of tumor: primary; Age at diagnosis: 49.5 years (18,071 days); Year of diagnosis: 2003; Method of diagnosis: Excisional Biopsy; Prior treatment: No.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carmustine Implant; Treatment intent type: Adjuvant; Days to treatment start: 0 days; Days to treatment end: 0 days; Number of cycles: 1; Treatment dose: 8 Wafer; Route of administration: Intratumoral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Treatment intent type: Adjuvant; Days to treatment start: 9 days; Days to treatment end: 65 days; Number of cycles: 2; Treatment dose: 150 mg/m2; Route of administration: Oral.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Days to treatment start: 24 days; Days to treatment end: 65 days; Treatment dose: 6,000 cGy; Number of fractions: 30; Treatment anatomic sites: Primary Tumor Field.

Follow-up (2 entries)
- Karnofsky performance status: 60; Timepoint: Prior to Adjuvant Therapy.
- Follow-up contacts recording only the day: day 50, day 395.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-12-0618-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1.2; Intermediate dimension: 0.6; Shortest dimension: 0.5.
  Slide TCGA-12-0618-01A-01-BS1: Section location: Bottom; Percent tumor cells: 90; Percent tumor nuclei: 100; Percent normal cells: 0; Percent necrosis: 10; Percent stromal cells: 0.
  Slide TCGA-12-0618-01A-01-TS1: Section location: Top; Percent tumor cells: 97; Percent tumor nuclei: 100; Percent normal cells: 0; Percent necrosis: 3; Percent stromal cells: 0.
- Sample TCGA-12-0618-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-12-0618-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Untreated primary (de novo) GBM; History lgg diagnosis of brain tissue: No; History neoadjuvant treatment: No; Performance status timing: Pre-Adjuvant Therapy.
- Drug treatment 1: Pharmaceutical therapy drug name: Gliadel wafers.
- Drug treatment 1, Route of administrations: Route of administration: Intum.
- Drug treatment 2: Pharmaceutical therapy drug name: Temodar.
- Drug treatment 2, Route of administrations: Route of administration: PO.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 395 days; disease-specific survival: event status not recorded, 395 days; progression-free interval: no event (censored), 395 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-12-0618-01A-01D-0310-01): tumor purity 0.95, ploidy 2, whole-genome doublings 0.
